Somatic mutation profile of tumor specimen TCGA-BR-6803-01A (aliquot TCGA-BR-6803-01A-11D-1882-08) from TCGA case TCGA-BR-6803, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 54.1 years (19,751 days).
Specimen TCGA-BR-6803-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53e1d08a-ac1d-4088-818e-c9e3d0671398.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6803-10A (Blood Derived Normal), aliquot TCGA-BR-6803-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05efeab8-adbe-4dae-b6a2-fe19f0ab3339

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 63/224 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555515445, CM1511046, COSV55727198, COSV55729198, COSV55735587; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2
- AK3 | c.612T>G p.I204M | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs746411663, COSV63346377; called by muse, mutect2, varscan2
- CHID1 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as rs771369989, COSV60258036; called by muse, mutect2, varscan2
- PCDHGA8 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.094); catalogued as rs141295392; called by muse, mutect2, varscan2
- SPAG5 | c.3211G>A p.E1071K | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56885624; called by muse, mutect2, varscan2
- SVIL | c.5801C>T p.T1934M (on ENST00000355867 / NM_021738.3; = p.T1508M on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs746667526, COSV63440730; called by muse, mutect2, varscan2
- NRXN1 | c.1851del p.L618Cfs*51 | Frame Shift Del (DEL) | VAF 19/162 reads (12%) | called by mutect2, pindel, varscan2
- ATP7A | c.2262C>A p.T754= | Silent (SNP) | VAF 14/318 reads (4%) | called by muse, mutect2
- DOCK1 | c.2223G>T p.A741= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs761104711, COSV54732133, COSV54746758; called by muse, mutect2
- GPR155 | c.2301C>G p.V767= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV55037756; called by muse, mutect2
- MAGEB1 | c.990G>T p.T330= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV66775315, COSV66775324; called by muse, mutect2, varscan2
- PSD4 | c.2535G>A p.S845= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV55525007; called by muse, mutect2, varscan2
